Gene-level copy-number profile of tumor specimen TCGA-VQ-A8E2-01A from TCGA case TCGA-VQ-A8E2, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 57.8 years (21,112 days).
Specimen TCGA-VQ-A8E2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.03401783-3c60-4422-be65-1cd57846ce84.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-VQ-A8E2-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/4f82464f-0b7b-4a79-bbb8-d2cab1d0319b

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 9; copy number 1: 309; copy number 2: 3,760; copy number 3: 13,512; copy number 4: 18,876; copy number 5: 17,542; copy number 6: 2,757; copy number 7: 1,359; copy number 8: 46; copy number 9: 309; copy number 10: 38; copy number 12: 1,136; copy number 13: 48; copy number 15: 4; copy number 16: 8; copy number 17: 2; copy number 22: 52; copy number 27: 18; copy number 32: 19; copy number 63: 11.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-VQ-A8E2-01A-11D-A363-01): tumor purity 0.39, ploidy 4.29, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,645 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:206,747,980–207,150,281, 17 genes, copy number 9: Y_RNA, IL10, IL19, IL20, IL24, FCMR, AC098935.2, AC098935.1, PIGR, FCAMR, C1orf116, PFKFB2, YOD1, C4BPB, C4BPA, AL445493.3, AL445493.1.
- chr2:189,879,609–190,344,193, 6 genes, copy number 9: C2orf88, TERF1P6, HNRNPCP2, RNF11P1, MSTN, HIBCH.
- chr6:43,171,269–44,089,288, 42 genes, copy number 9 (within-gene range 6–9): SRF, CUL9, AL133375.1, DNPH1, TTBK1, SLC22A7, CRIP3, ZNF318, RPL12P47, AL583834.1, RPS2P28, AL590383.1, AL359813.1, AL359813.2, ABCC10, MIR6780B, DLK2, RNU6-1113P, TJAP1, LRRC73, POLR1C, YIPF3, AL355802.3, XPO5, AL355802.1, AL355802.2, POLH, POLH-AS1, GTPBP2, MAD2L1BP, RSPH9, MRPS18A, AL136131.1, AL136131.2, VEGFA, AL136131.3, AL157371.2, LINC02537, AL157371.1, AL109615.3, C6orf223, AL109615.2.
- chr8:125,859,721–128,388,636, 42 genes, copy number 9–22 (within-gene range 8–22): LINC00861, RNU6-442P, SOD1P3, AC024681.2, KNOP1P5, AC024681.1, RFPL4AP5, AC087667.1, AC084116.2, AC084116.1, RNU6-869P, AC084116.3, LRATD2, PCAT1, AC083923.1, RNU11-4P, AC024382.1, CASC19, PRNCR1, AC020688.1, AC018714.2, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, AC108925.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226, AC100822.1.
- chr8:140,657,900–141,002,216, 1 gene, copy number 22 (within-gene range 4–22): PTK2.
- chr8:140,820,599–141,392,574, 15 genes, copy number 22: AC105235.1, RNA5SP278, AC100860.1, DENND3, AC040970.1, SLC45A4, AC011676.5, AC011676.1, AC011676.2, AC011676.3, AC011676.4, LINC01300, AC100803.3, GPR20, AC100803.2.
- chr8:142,212,080–142,640,648, 8 genes, copy number 9 (within-gene range 6–9): TSNARE1, RN7SL260P, AC134682.1, ADGRB1, MROH4P, ARC, AP006547.1, AC108002.2.
- chr13:73,036,401–73,408,352, 8 genes, copy number 16: PSMD10P3, KLF5, FABP5P1, RNU6-66P, RNU4-10P, RNY1P8, AL162376.1, MARK2P12.
- chr19:28,869,507–31,427,302, 48 genes, copy number 27–63: AC007795.1, LINC00906, AC008991.1, AC011524.1, AC011524.2, RNA5SP470, LINC01532, AC011505.1, UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC008507.4, AC008507.5, AC005597.1, ZNF536, AC011504.1, AC011478.1, AC011507.1, LINC01834, AC020897.1, AC020912.1, TSHZ3, LINC01791, AC025809.1, AC025809.2, AC008992.1.
- chr20:87,250–64,313,132, 1,458 genes, copy number 9–15 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
